Somatic mutation profile of tumor specimen HCM-CSHL-0618-C18-06A (aliquot HCM-CSHL-0618-C18-06A-11D-A881-36) from HCMI case HCM-CSHL-0618-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 84.9 years (31,013 days).
Specimen HCM-CSHL-0618-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b8715e5-061d-4594-8dc3-35befee6b730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0618-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0618-C18-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edadb9d0-742b-4893-b212-3c255b129635

The open-access MAF lists 114 somatic variants for this specimen: 82 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 26, Nonsense Mutation 3, 5'Flank 2, Frame Shift Del 2, Intron 1, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 105/385 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1610A>T p.D537V | Missense Mutation (SNP) | VAF 161/376 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684111, COSV61685387, COSV61697211; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 122/369 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs144784477, COSV100711660; called by muse, mutect2, varscan2
- AIMP2 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 123/425 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762651435; called by muse, mutect2, varscan2
- ALDH1A2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 181/421 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs137957671; called by muse, mutect2, varscan2
- APC | c.4717G>T p.E1573* | Nonsense Mutation (SNP) | VAF 127/333 reads (38%) | catalogued as CM053766, COSV104439189, COSV57323709, COSV57324336, COSV57334217; called by muse, mutect2, varscan2
- ASCL2 | c.148_166del p.A50Mfs*8 | Frame Shift Del (DEL) | VAF 224/830 reads (27%) | catalogued as rs778974931; called by mutect2, varscan2
- BCL11A | c.1627G>A p.E543K (on ENST00000335712 / NM_001365609.1; = p.E577K on NM_018014.4) | Missense Mutation (SNP) | VAF 321/1095 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.122); catalogued as COSV100184567; called by muse, mutect2, varscan2
- CENPN | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234248777, COSV59904511; called by muse, mutect2, varscan2
- CHST5 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 165/612 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1421909496; called by muse, mutect2, varscan2
- CPEB1 | c.1028G>A p.R343Q (on ENST00000617958; = p.R283Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV55621849; called by muse, mutect2, varscan2
- CRHR2 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 104/428 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756036342; called by muse, mutect2, varscan2
- CROCC2 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 186/714 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753481966; called by muse, mutect2, varscan2
- CSMD1 | c.2564G>A p.R855H (on ENST00000520002; = p.R854H on NM_033225.6) | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as rs376486567; called by muse, mutect2
- CTNNA3 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 160/502 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139378888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCHS1 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 96/600 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172174294; called by muse, mutect2, varscan2
- DLG2 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as rs1326969221; called by muse, mutect2, varscan2
- EEF2 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 90/605 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58578932; called by muse, mutect2, varscan2
- ERC2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 91/358 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs758640784, COSV99884332; called by muse, mutect2, varscan2
- FAM47C | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 227/431 reads (53%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1271779756; called by muse, mutect2, varscan2
- GPR119 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 360/519 reads (69%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs140173805, COSV52275676; called by muse, mutect2, varscan2
- HDAC9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400537160, COSV67769993; called by muse, mutect2, varscan2
- HOXB3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 95/600 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV57488141; called by muse, mutect2, varscan2
- LAMB4 | c.4289G>C p.R1430P | Missense Mutation (SNP) | VAF 107/398 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52732914; called by muse, mutect2, varscan2
- LONRF3 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 510/716 reads (71%) | SIFT tolerated (0.36); PolyPhen benign (0.092); catalogued as rs1464876632; called by muse, mutect2, varscan2
- MSX1 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 154/807 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765128034; called by muse, mutect2, varscan2
- MYH7 | c.4807G>A p.A1603T | Missense Mutation (SNP) | VAF 227/664 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs730880809, CM146982, COSV62520693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs756530426, COSV55449131; called by muse, mutect2, varscan2
- PILRA | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 118/758 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as rs753428938, COSV52199660; called by muse, varscan2
- PLPPR5 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 190/518 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54174184; called by muse, varscan2
- PSG4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 124/371 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs769047324, COSV54938968, COSV99737771; called by muse, mutect2, varscan2
- RABGAP1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171254387; called by muse, mutect2, varscan2
- RET | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 82/596 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs545625150, CM159816, COSV60701403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB2 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 58/285 reads (20%) | catalogued as rs1346573627; called by muse, mutect2, varscan2
- SCN11A | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs777323474, COSV56567930, COSV56568066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 56/684 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs753391449; called by muse, mutect2
- SPATA48 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1299431753; called by muse, mutect2
- SPNS2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 97/599 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985236722; called by muse, mutect2, varscan2
- TBC1D3B | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as rs1330136710; called by muse, mutect2, varscan2
- TIGD3 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV52887896; called by muse, mutect2, varscan2
- TLE2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 76/537 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568657687; called by muse, varscan2
- TNC | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 86/518 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs763289734, COSV60785514; called by muse, mutect2, varscan2
- ZNF222 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as rs117318348; called by muse, mutect2, varscan2
- ZNF804A | c.3025G>C p.E1009Q | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100168284; called by muse, varscan2
- AAR2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 44/493 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2
- ADA2 | c.1316G>T p.S439I (on ENST00000262607; = p.S198I on NM_177405.3) | Missense Mutation (SNP) | VAF 133/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC | c.1488_1489dup p.L497Hfs*2 | Frame Shift Ins (INS) | VAF 32/326 reads (10%) | called by mutect2, pindel, varscan2
- ASPH | c.1379T>G p.L460R | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BNIP1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 58/390 reads (15%) | called by muse, mutect2, varscan2
- C10orf71 | c.2954G>C p.C985S | Missense Mutation (SNP) | VAF 161/612 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC14 | c.823C>T p.P275S (on ENST00000488653; = p.P227S on NM_022757.5) | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CD86 | c.571G>C p.D191H (on ENST00000330540 / NM_175862.5; = p.D185H on NM_006889.4) | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CFAP74 | c.101T>A p.I34N | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.731); called by mutect2, varscan2
- FBXO9 | c.1128_1140del p.Q377Rfs*56 | Frame Shift Del (DEL) | VAF 144/383 reads (38%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.1801A>G p.K601E | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- HDAC5 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 136/373 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HTR1B | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HYDIN | c.10406C>T p.A3469V | Missense Mutation (SNP) | VAF 97/404 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD19 | c.273G>T p.L91F | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LCP2 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MUC16 | c.14890C>A p.P4964T | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- NUSAP1 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OPRD1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 234/979 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- OR2M3 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- OR6C3 | c.233T>A p.F78Y | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- PCM1 | c.5345C>G p.S1782C | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKD1L3 | c.5101A>C p.N1701H | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PLA2G4F | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 196/464 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2
- PRLHR | c.1023C>G p.S341R | Missense Mutation (SNP) | VAF 111/481 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRB | c.5575C>T p.L1859F | Missense Mutation (SNP) | VAF 132/466 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PXDN | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); called by muse, mutect2
- RAD51D | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SIPA1L2 | c.4105T>G p.Y1369D | Missense Mutation (SNP) | VAF 85/423 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SORCS1 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5L | c.3020+7G>T | Splice Region (SNP) | VAF 98/367 reads (27%) | called by muse, mutect2, varscan2
- SYCP1 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TBC1D26 | c.22T>A p.Y8N | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); called by mutect2, varscan2
- TRPS1 | c.3325G>T p.D1109Y (on ENST00000220888 / NM_001330599.2; = p.D1122Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/475 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- URB1 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 171/490 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- WAS | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZSCAN16 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 39/665 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ACTN4 | c.54G>A p.A18= | Silent (SNP) | VAF 106/746 reads (14%) | called by muse, mutect2, varscan2
- AEBP1 | c.75G>A p.P25= | Silent (SNP) | VAF 196/725 reads (27%) | called by muse, varscan2
- ANKFN1 | c.3414C>T p.S1138= (on ENST00000653862; = p.S991= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 87/561 reads (16%) | catalogued as rs1041991870; called by muse, mutect2, varscan2
- ANKRD10 | c.459G>A p.L153= | Silent (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
- ANKRD55 | c.450G>A p.S150= | Silent (SNP) | VAF 42/340 reads (12%) | catalogued as rs747861739, COSV61946235; called by muse, mutect2
- BAZ1B | c.2124A>G p.S708= | Silent (SNP) | VAF 95/394 reads (24%) | called by muse, mutect2, varscan2
- CABLES1 | c.1683G>T p.L561= (on ENST00000256925 / NM_001100619.2; = p.L296= on NM_138375.2) | Silent (SNP) | VAF 75/436 reads (17%) | called by muse, mutect2, varscan2
- CCDC14 | c.822G>T p.L274= (on ENST00000488653; = p.L226= on NM_022757.5) | Silent (SNP) | VAF 54/411 reads (13%) | called by muse, mutect2, varscan2
- CCR7 | c.354G>A p.A118= | Silent (SNP) | VAF 90/431 reads (21%) | catalogued as rs199621619; called by muse, mutect2, varscan2
- COL8A1 | c.1782C>T p.G594= | Silent (SNP) | VAF 176/498 reads (35%) | catalogued as rs377127489; called by muse, mutect2, varscan2
- EFS | c.522C>G p.T174= | Silent (SNP) | VAF 100/674 reads (15%) | called by muse, mutect2, varscan2
- IL11 | c.525C>T p.H175= | Silent (SNP) | VAF 204/722 reads (28%) | catalogued as rs544256358; called by muse, mutect2, varscan2
- IRS1 | c.3111C>G p.S1037= | Silent (SNP) | VAF 187/693 reads (27%) | catalogued as COSV59337654; called by muse, mutect2, varscan2
- LGI3 | c.1011C>T p.I337= | Silent (SNP) | VAF 105/454 reads (23%) | catalogued as rs773555136, COSV60443274; called by muse, mutect2, varscan2
- LRRC4B | c.1218C>T p.H406= | Silent (SNP) | VAF 193/637 reads (30%) | catalogued as rs752514581, COSV100975927; called by muse, mutect2, varscan2
- MORC1 | c.246C>T p.Y82= | Silent (SNP) | VAF 10/269 reads (4%) | called by muse, mutect2
- MSX1 | c.360G>T p.V120= | Silent (SNP) | VAF 152/807 reads (19%) | called by muse, mutect2, varscan2
- NIPAL4 | c.1242C>T p.C414= | Silent (SNP) | VAF 89/544 reads (16%) | catalogued as rs373794632; called by muse, mutect2, varscan2
- NUTM1 | c.834C>A p.I278= | Silent (SNP) | VAF 69/212 reads (33%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1866C>T p.G622= | Silent (SNP) | VAF 118/694 reads (17%) | catalogued as rs751642051, COSV53914791; called by muse, mutect2, varscan2
- RCAN1 | c.81G>C p.G27= | Silent (SNP) | VAF 286/925 reads (31%) | catalogued as rs1018546479; called by muse, mutect2, varscan2
- RFX1 | c.123G>A p.P41= | Silent (SNP) | VAF 28/531 reads (5%) | catalogued as rs761156872; called by muse, mutect2
- ROGDI | c.768C>T p.D256= | Silent (SNP) | VAF 144/530 reads (27%) | catalogued as rs753887163; called by muse, mutect2, varscan2
- UBE2O | c.1713C>T p.N571= | Silent (SNP) | VAF 112/373 reads (30%) | catalogued as rs747956830; called by muse, mutect2, varscan2
- UBTD1 | c.432C>T p.S144= | Silent (SNP) | VAF 220/876 reads (25%) | catalogued as rs1210329059; called by muse, mutect2, varscan2
- VEPH1 | c.1392C>T p.D464= | Silent (SNP) | VAF 108/316 reads (34%) | catalogued as rs113924904; called by muse, mutect2, varscan2
- CCDC169 | chr13:36227157 G>T | 3'Flank (SNP) | VAF 214/472 reads (45%) | called by muse, mutect2, varscan2
- FSIP2 | chr2:185738689 G>A | 5'Flank (SNP) | VAF 212/735 reads (29%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+444C>T | Intron (SNP) | VAF 70/162 reads (43%) | catalogued as rs1441260230; called by muse, mutect2, varscan2
- MYCBP2 | c.*59G>A | 3'UTR (SNP) | VAF 58/582 reads (10%) | catalogued as rs531263957; called by muse, mutect2
- NPAP1L | n.816C>T | RNA (SNP) | VAF 78/314 reads (25%) | catalogued as rs1294297918, COSV73747282; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26671822 C>A | 5'Flank (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
